FM case AD3996 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/ac60a5d2-6d23-4006-984b-96d46979447c

Female, 33.3 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the peritoneum; metastasis biopsied or resected from the specified parts of peritoneum. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
